FM case AD4101 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/542096b0-24fc-4d8e-a456-dbec83e384e0

Male, 53.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the lung; metastasis biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 25% (pathologist estimate recorded by GDC). Sample type: Metastatic.
